Somatic mutation profile of tumor specimen 0DSF00 from CCDI case PBCGIZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myofibroblastic tumor, NOS; Tissue or organ of origin: Ileum; Age at diagnosis: 12.5 years (4,561 days).
Specimen 0DSF00: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a1f8cd4-dc52-4657-88cb-48f39a2a88f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEYR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5ed9e32-bf7e-43c6-9d1e-9bdd7cfb116e

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRIG2 | c.2935A>C p.S979R | Missense Mutation (SNP) | VAF 58/689 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.019); called by muse, mutect2
- PCLO | c.11643G>A p.P3881= | Silent (SNP) | VAF 44/646 reads (7%) | catalogued as rs752565615, COSV100438990; called by muse, mutect2
- KRT17 | c.433-12C>G | Intron (SNP) | VAF 36/341 reads (11%) | called by muse, mutect2
